Somatic mutation profile of tumor specimen ALCH-B49V-TTP1-A (aliquot ALCH-B49V-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B49V, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.4 years (19,854 days).
Specimen ALCH-B49V-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d584ec7d-534a-4b12-8480-3f0701713684.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B49V-NB1-A (Blood Derived Normal), aliquot ALCH-B49V-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c49d6897-7bd8-435d-afbd-e9c3a4189494

The open-access MAF lists 157 somatic variants for this specimen: 112 protein-altering or splice-affecting, 27 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 27, Frame Shift Del 11, Intron 9, RNA 4, 3'UTR 3, Nonsense Mutation 3, Splice Region 2, Splice Site 2, Frame Shift Ins 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 127/416 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAMTS13 | c.1672C>T p.R558W | Missense Mutation (SNP) | VAF 20/267 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as rs782055634; called by muse, mutect2
- AGAP2 | c.3081-1G>A p.X1027_splice (on ENST00000547588 / NM_001122772.2; = p.X671_splice on NM_014770.4) | Splice Site (SNP) | VAF 24/74 reads (32%) | catalogued as COSV99222983; called by muse, mutect2, varscan2
- ARMCX2 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.001); catalogued as rs1556060113; called by muse, mutect2
- ASXL3 | c.179C>A p.T60N | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52473268; called by muse, mutect2, varscan2
- ASXL3 | c.1471C>A p.Q491K | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.057); catalogued as COSV99324408; called by muse, mutect2, varscan2
- ATRX | c.3402G>T p.L1134F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.084); catalogued as COSV100971080; called by muse, mutect2, varscan2
- AXL | c.1820G>T p.G607V (on ENST00000301178 / NM_021913.5; = p.G598V on NM_001699.6) | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.899); catalogued as COSV56564942; called by muse, mutect2
- CACNA1F | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); catalogued as CM030201; called by muse, mutect2
- CDH7 | c.2240C>A p.S747Y | Missense Mutation (SNP) | VAF 73/465 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100542504; called by muse, mutect2, varscan2
- CLCA2 | c.1667A>T p.N556I | Missense Mutation (SNP) | VAF 46/236 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV65286959; called by muse, mutect2, varscan2
- CNKSR2 | c.2105G>T p.S702I | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.701); catalogued as COSV99670218; called by muse, mutect2, varscan2
- CYBA | c.288-3C>T | Splice Region (SNP) | VAF 16/84 reads (19%) | catalogued as COSV55367982; called by muse, mutect2, varscan2
- DENND11 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs778109586; called by muse, mutect2, varscan2
- DNAH14 | c.3848C>A p.S1283Y (on ENST00000445597; = p.S1693Y on NM_001367479.1) | Missense Mutation (SNP) | VAF 9/225 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as rs1420169318; called by muse, mutect2
- DPT | c.45G>T p.M15I | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63189586; called by muse, mutect2
- EFCAB13 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs377500863; called by muse, mutect2, varscan2
- FGFR1 | c.2351G>A p.R784Q (on ENST00000447712 / NM_023110.3; = p.R782Q on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs746602135, COSV58331843; called by muse, mutect2, varscan2
- FHOD3 | c.2621del p.G874Afs*2 (on ENST00000359247 / NM_001281739.3; = p.G891Afs*2 on NM_025135.5) | Frame Shift Del (DEL) | VAF 31/310 reads (10%) | catalogued as COSV57172288; called by mutect2, pindel
- G6PD | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM123589, COSV63703602; called by muse, mutect2
- GPR148 | c.1013G>T p.R338M | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as COSV59308525; called by muse, mutect2, varscan2
- GPR148 | c.1014G>T p.R338S | Missense Mutation (SNP) | VAF 29/228 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.109); catalogued as COSV59308433; called by muse, mutect2, varscan2
- GRM3 | c.1876T>A p.Y626N | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1478890379; called by muse, mutect2, varscan2
- IL18RAP | c.383C>A p.P128H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV51826899; called by muse, mutect2
- LRRC7 | c.4535C>A p.P1512H (on ENST00000651989 / NM_001370785.2; = p.P1432H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99223781; called by muse, mutect2, varscan2
- MARF1 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 72/396 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200454458; called by muse, mutect2, varscan2
- MED23 | c.3070C>T p.R1024* | Nonsense Mutation (SNP) | VAF 70/375 reads (19%) | catalogued as rs777057285; called by muse, mutect2, varscan2
- MEF2C | c.219C>G p.N73K | Missense Mutation (SNP) | VAF 60/353 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768621677; called by muse, mutect2, varscan2
- NEIL3 | c.172A>T p.N58Y | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as rs908984320; called by muse, mutect2
- NLGN4X | c.2372C>G p.P791R | Missense Mutation (SNP) | VAF 59/377 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.14); catalogued as COSV99320526; called by muse, mutect2, varscan2
- PFKM | c.2140C>T p.R714C | Missense Mutation (SNP) | VAF 48/653 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100402614; called by muse, mutect2
- RBM10 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV52101874; called by muse, mutect2
- RHOXF2 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 53/432 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.375); catalogued as rs782736349; called by muse, mutect2, varscan2
- RNF31 | c.2197G>T p.A733S | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV100141805; called by muse, mutect2, varscan2
- RPL11 | c.140C>T p.P47L (on ENST00000374550 / NM_001199802.1; = p.P48L on NM_000975.5) | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs1283851298; called by muse, mutect2, varscan2
- SIL1 | c.1145C>T p.T382M | Missense Mutation (SNP) | VAF 58/354 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs369750441, COSV54528124; called by muse, mutect2, varscan2
- SLC12A1 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317299207; called by muse, mutect2, varscan2
- SLC8A1 | c.1079G>C p.S360T | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1398007162; called by muse, mutect2, varscan2
- SPTA1 | c.6347C>A p.S2116Y | Missense Mutation (SNP) | VAF 70/389 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV63761052; called by muse, mutect2, varscan2
- TMEM185B | c.563A>G p.Y188C | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1222336404; called by muse, mutect2, varscan2
- TULP4 | c.4461del p.R1488Gfs*2 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | catalogued as rs749489411; called by mutect2, pindel, varscan2
- ACMSD | c.787T>C p.Y263H | Missense Mutation (SNP) | VAF 57/373 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AKAIN1 | c.76G>A p.V26M | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AL031777.2 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 53/317 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGAP9 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATP6AP1 | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATXN2 | c.3430A>G p.T1144A (on ENST00000550104; = p.T984A on NM_002973.4) | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- BCHE | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 39/279 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C10orf67 | c.1639G>C p.E547Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- C2orf74 | c.116G>C p.C39S | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- CAMK2A | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCPG1 | c.1370A>G p.D457G | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2
- CELSR3 | c.1703C>T p.T568M | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- CNGA2 | c.499C>A p.L167I | Missense Mutation (SNP) | VAF 10/175 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2
- CSMD3 | c.5300C>A p.T1767K (on ENST00000297405 / NM_001363185.1; = p.T1663K on NM_052900.3) | Missense Mutation (SNP) | VAF 56/395 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- CYFIP2 | c.2553G>T p.E851D (on ENST00000616178 / NM_001291722.2; = p.E826D on NM_014376.4) | Missense Mutation (SNP) | VAF 48/307 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- CYYR1 | c.17del p.L6Hfs*65 | Frame Shift Del (DEL) | VAF 23/209 reads (11%) | called by mutect2, pindel, varscan2
- DNAH3 | c.4820del p.K1607Sfs*10 | Frame Shift Del (DEL) | VAF 84/530 reads (16%) | called by mutect2, pindel, varscan2
- EARS2 | c.337G>T p.G113W | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPB41L3 | c.97G>T p.V33L | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPDR1 | c.461G>T p.R154I | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FKTN | c.617A>T p.Q206L | Missense Mutation (SNP) | VAF 21/370 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- GBE1 | c.273G>T p.W91C | Missense Mutation (SNP) | VAF 38/393 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GUCY2F | c.2526del p.T843Lfs*15 | Frame Shift Del (DEL) | VAF 55/312 reads (18%) | called by mutect2, pindel, varscan2
- HNRNPA3 | c.1058del p.G353Efs*52 (on ENST00000392524; = p.G353Efs*62 on NM_194247.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 24/148 reads (16%) | called by mutect2, pindel, varscan2
- HSPB3 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 14/504 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- IGHG2 | c.350del p.P117Rfs*15 | Frame Shift Del (DEL) | VAF 14/100 reads (14%) | called by mutect2, pindel, varscan2
- IGKV3D-11 | c.28del p.L10Sfs*15 | Frame Shift Del (DEL) | VAF 22/116 reads (19%) | called by mutect2, varscan2
- IL17RD | c.500C>A p.P167H | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- KCNH1 | c.1108C>A p.H370N (on ENST00000271751 / NM_172362.3; = p.H343N on NM_002238.4) | Missense Mutation (SNP) | VAF 51/276 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- KLHL15 | c.608C>A p.S203Y | Missense Mutation (SNP) | VAF 38/314 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- KRT26 | c.1205G>T p.C402F | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KRTAP26-1 | c.430C>G p.R144G | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LCP2 | c.44G>C p.W15S | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB17 | c.162del p.N55Mfs*55 | Frame Shift Del (DEL) | VAF 48/220 reads (22%) | called by mutect2, pindel, varscan2
- MCC | c.2015A>T p.E672V | Missense Mutation (SNP) | VAF 37/318 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MUC19 | c.274G>C p.A92P | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2
- MUC22 | c.3157A>G p.K1053E | Missense Mutation (SNP) | VAF 77/403 reads (19%) | SIFT tolerated (1); called by muse, mutect2, varscan2
- NAGPA | c.260A>T p.D87V | Missense Mutation (SNP) | VAF 11/37 reads (30%) | PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NAV3 | c.4043C>G p.A1348G | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.427); called by muse, mutect2
- NDST4 | c.697G>T p.V233L | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.516); called by muse, mutect2
- NELL1 | c.490C>A p.H164N | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- NPEPL1 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- NPHS1 | c.938C>A p.A313E | Missense Mutation (SNP) | VAF 55/282 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NPY5R | c.1009T>A p.F337I | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NR4A3 | c.697A>T p.S233C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- NRXN1 | c.4078A>T p.S1360C | Missense Mutation (SNP) | VAF 101/577 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- OR4P4 | c.715A>T p.S239C | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- OR5D14 | c.711C>A p.H237Q | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PALLD | c.194C>G p.S65W | Missense Mutation (SNP) | VAF 53/515 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- PCF11 | c.2225T>C p.L742P | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- PDZRN3 | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- PLXNA3 | c.1820G>T p.R607M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- POMT2 | c.1973G>C p.G658A | Missense Mutation (SNP) | VAF 45/394 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- PRDM14 | c.521C>G p.P174R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- RELN | c.1988G>T p.W663L | Missense Mutation (SNP) | VAF 88/587 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- RPH3A | c.1858-1G>T p.X620_splice (on ENST00000389385 / NM_001143854.2; = p.X616_splice on NM_014954.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 34/116 reads (29%) | called by muse, mutect2, varscan2
- SFTPB | c.890_891del p.S297* | Frame Shift Del (DEL) | VAF 58/468 reads (12%) | called by pindel, varscan2
- SUGT1 | c.1036G>T p.D346Y (on ENST00000343788 / NM_001130912.3; = p.D314Y on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TECTA | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 61/286 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- TFAP2B | c.1032C>G p.H344Q | Missense Mutation (SNP) | VAF 121/549 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMEM132D | c.1498G>T p.V500F | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- TMEM260 | c.2045dup p.Q683Tfs*4 | Frame Shift Ins (INS) | VAF 72/484 reads (15%) | called by mutect2, pindel, varscan2
- TPO | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 45/321 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1418G>A p.C473Y | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.397); called by muse, varscan2
- TRPC6 | c.1363G>T p.G455* | Nonsense Mutation (SNP) | VAF 87/543 reads (16%) | called by muse, mutect2, varscan2
- USP34 | c.9464T>G p.V3155G | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- VN1R2 | c.288G>T p.Q96H | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- ZNF12 | c.237A>C p.P79= | Splice Region (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- ZNF568 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 52/240 reads (22%) | called by muse, mutect2, varscan2
- ZNF75A | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- ZNF99 | c.1124del p.G375Afs*15 | Frame Shift Del (DEL) | VAF 33/250 reads (13%) | called by mutect2, pindel, varscan2
- ALDH3B2 | c.546C>T p.A182= | Silent (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- ASCL1 | c.696C>T p.F232= | Silent (SNP) | VAF 10/244 reads (4%) | called by muse, mutect2
- ASPM | c.7236C>A p.T2412= | Silent (SNP) | VAF 78/582 reads (13%) | called by muse, mutect2, varscan2
- BRDT | c.393T>C p.S131= | Silent (SNP) | VAF 26/179 reads (15%) | called by muse, mutect2, varscan2
- CCDC110 | c.354A>T p.T118= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- CLEC4C | c.540T>C p.C180= | Silent (SNP) | VAF 63/208 reads (30%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.2877C>T p.H959= | Silent (SNP) | VAF 28/384 reads (7%) | called by muse, mutect2
- COL6A6 | c.360T>A p.S120= | Silent (SNP) | VAF 39/200 reads (20%) | called by muse, mutect2, varscan2
- DOCK1 | c.2277G>C p.L759= | Silent (SNP) | VAF 47/264 reads (18%) | called by muse, mutect2, varscan2
- DYNC2I2 | c.345G>A p.V115= | Silent (SNP) | VAF 32/173 reads (18%) | called by muse, mutect2, varscan2
- FCGR2A | c.6T>A p.T2= | Silent (SNP) | VAF 16/286 reads (6%) | catalogued as COSV54837038; called by muse, mutect2
- G6PD | c.738C>T p.R246= | Silent (SNP) | VAF 17/248 reads (7%) | catalogued as rs144341068, COSV63703011; called by muse, mutect2
- GRIA1 | c.1191T>A p.A397= | Silent (SNP) | VAF 8/135 reads (6%) | called by muse, mutect2
- HOXD11 | c.477C>A p.G159= | Silent (SNP) | VAF 28/147 reads (19%) | catalogued as rs1292272751; called by muse, mutect2, varscan2
- ICE1 | c.678C>T p.S226= | Silent (SNP) | VAF 41/293 reads (14%) | catalogued as rs751954450; called by muse, mutect2, varscan2
- IRX6 | c.78C>T p.C26= | Silent (SNP) | VAF 17/103 reads (17%) | called by mutect2, varscan2
- LRRC4C | c.1470C>A p.T490= | Silent (SNP) | VAF 27/167 reads (16%) | called by muse, mutect2, varscan2
- OR51B6 | c.117C>G p.G39= | Silent (SNP) | VAF 33/363 reads (9%) | called by muse, mutect2
- OR5P3 | c.843G>T p.V281= | Silent (SNP) | VAF 102/530 reads (19%) | catalogued as COSV60428976; called by muse, mutect2, varscan2
- PPP1R32 | c.528G>T p.T176= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as rs376746004; called by muse, mutect2, varscan2
- PRSS21 | c.573C>A p.L191= | Silent (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- PRUNE2 | c.3195C>A p.I1065= | Silent (SNP) | VAF 17/170 reads (10%) | called by muse, mutect2
- RCC1 | c.36C>T p.P12= | Silent (SNP) | VAF 39/291 reads (13%) | catalogued as rs747986079, COSV100868146; called by muse, mutect2, varscan2
- TEX13C | c.2178G>C p.L726= | Silent (SNP) | VAF 73/475 reads (15%) | called by muse, varscan2
- TRPM1 | c.4275C>A p.P1425= | Silent (SNP) | VAF 160/857 reads (19%) | catalogued as COSV56643083; called by muse, mutect2, varscan2
- ZFYVE26 | c.780C>A p.L260= | Silent (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- ZNF610 | c.570A>C p.P190= | Silent (SNP) | VAF 20/128 reads (16%) | called by muse, mutect2, varscan2
- AC021218.1 | n.375G>C | RNA (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
- AC073310.1 | n.820G>T | RNA (SNP) | VAF 8/80 reads (10%) | called by mutect2, varscan2
- BCAS3 | c.2075-4972G>T | Intron (SNP) | VAF 74/435 reads (17%) | called by muse, mutect2, varscan2
- CLK2P1 | n.770G>T | RNA (SNP) | VAF 65/428 reads (15%) | called by muse, mutect2, varscan2
- COX6A1P2 | n.97G>T | RNA (SNP) | VAF 14/354 reads (4%) | called by muse, mutect2
- ECI2 | c.50+333C>T | Intron (SNP) | VAF 34/229 reads (15%) | called by muse, mutect2, varscan2
- FGF14 | c.608-34T>G | Intron (SNP) | VAF 66/378 reads (17%) | called by muse, mutect2, varscan2
- HMGN2 | c.60+22G>T | Intron (SNP) | VAF 27/172 reads (16%) | called by muse, mutect2, varscan2
- HOXC11 | c.*71T>A | 3'UTR (SNP) | VAF 57/162 reads (35%) | called by muse, mutect2, varscan2
- ITIH1 | c.1925-60C>A | Intron (SNP) | VAF 13/130 reads (10%) | called by muse, mutect2, varscan2
- LTN1 | c.-47G>A | 5'UTR (SNP) | VAF 53/309 reads (17%) | catalogued as COSV57478281; called by muse, mutect2, varscan2
- MARCHF8 | c.242+821T>G | Intron (SNP) | VAF 14/314 reads (4%) | catalogued as rs1190578422; called by muse, mutect2
- NOBOX | c.210+893C>A | Intron (SNP) | VAF 25/151 reads (17%) | called by muse, mutect2, varscan2
- PLA2G6 | c.798-16G>T | Intron (SNP) | VAF 24/150 reads (16%) | catalogued as rs1358733353; called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159095 C>A | 5'Flank (SNP) | VAF 26/209 reads (12%) | called by muse, mutect2, varscan2
- TINF2 | c.1062-21C>T | Intron (SNP) | VAF 103/653 reads (16%) | catalogued as rs532494516, COSV99945466; called by muse, mutect2, varscan2
- TNFRSF18 | c.*210G>T | 3'UTR (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- ZNF99 | c.*1032G>T | 3'UTR (SNP) | VAF 23/151 reads (15%) | called by muse, mutect2, varscan2
